Somatic mutation profile of tumor specimen TCGA-OR-A5J8-01A (aliquot TCGA-OR-A5J8-01A-11D-A29I-10) from TCGA case TCGA-OR-A5J8, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 66.4 years (24,266 days).
Specimen TCGA-OR-A5J8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fc44db4-c94d-408a-8533-3314fe8fc0dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5J8-10A (Blood Derived Normal), aliquot TCGA-OR-A5J8-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98cf6560-77e4-4871-bcd4-b8eb964b3b22

The open-access MAF lists 97 somatic variants for this specimen: 74 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 20, Nonsense Mutation 10, Splice Site 2, Splice Region 2, 5'UTR 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 111/180 reads (62%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ADGRG6 | c.2349G>T p.K783N | Missense Mutation (SNP) | VAF 15/265 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.111); catalogued as COSV51601622; called by muse, mutect2
- AMER3 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs200636300, COSV100366224, COSV58467211; called by muse, mutect2, varscan2
- ATP5PB | c.449T>C p.I150T | Missense Mutation (SNP) | VAF 186/302 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs1207044789; called by muse, varscan2
- CCDC88C | c.5552C>T p.P1851L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1354103913; called by muse, mutect2, varscan2
- CDH22 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1052248062; called by muse, mutect2
- CFAP47 | c.2558C>A p.S853Y | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV52887871; called by muse, mutect2, varscan2
- DMXL2 | c.7852C>T p.L2618F | Missense Mutation (SNP) | VAF 91/139 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1318188039, COSV51856216; called by muse, mutect2, varscan2
- ENPEP | c.2233C>A p.R745S | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777524141, COSV54449266; called by muse, mutect2, varscan2
- FAT3 | c.6790C>A p.L2264I | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV53142415; called by muse, mutect2, varscan2
- HECW2 | c.3374G>T p.G1125V | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV53669608; called by muse, mutect2
- HSPBP1 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs767671307; called by muse, varscan2
- KCNQ4 | c.1293C>G p.S431R | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as COSV61274762; called by muse, mutect2, varscan2
- KDM2B | c.2133C>G p.D711E | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.051); catalogued as rs371581440; called by muse, mutect2, varscan2
- NEB | c.9318C>A p.S3106R | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs763268909; called by muse, mutect2
- OBSCN | c.13586C>G p.A4529G | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as COSV52816686; called by muse, mutect2, varscan2
- OR2A14 | c.133T>G p.F45V | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs762557646, COSV101376443; called by muse, mutect2
- SLCO6A1 | c.1330G>T p.V444F | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV65814748; called by muse, mutect2, varscan2
- SPEF2 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as rs899639741, COSV56795057; called by muse, mutect2, varscan2
- SSTR1 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs1268118179, COSV57455521; called by muse, mutect2, varscan2
- TTBK1 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 68/395 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as rs1386865480; called by muse, mutect2, varscan2
- ZNF236 | c.3913G>C p.D1305H | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53493968; called by muse, mutect2, varscan2
- ABCC3 | c.2133C>A p.F711L | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADAM23 | c.1859C>A p.A620E | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- BEGAIN | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- BTD | c.387C>A p.F129L | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- CHD9 | c.5405A>G p.Q1802R | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- CMC2 | c.107A>G p.Y36C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- DBH | c.1414G>T p.D472Y | Missense Mutation (SNP) | VAF 23/266 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- DHCR7 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.312); called by mutect2, varscan2
- DLEC1 | c.1150T>C p.Y384H | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH3 | c.10283C>A p.A3428D | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EVPL | c.5547G>T p.M1849I | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- EXOC3 | c.22G>C p.A8P | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- FGFBP2 | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 41/51 reads (80%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FGGY | c.466-1G>T p.X156_splice | Splice Site (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- FUT3 | c.774G>T p.E258D | Missense Mutation (SNP) | VAF 36/316 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLT6D1 | c.196C>A p.L66M | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSTCD | c.1528G>T p.G510* (on ENST00000360505 / NM_001031720.3; = p.G423* on NM_024751.3) | Nonsense Mutation (SNP) | VAF 46/79 reads (58%) | called by muse, mutect2, varscan2
- HLTF | c.1993A>T p.I665F | Missense Mutation (SNP) | VAF 77/111 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- IFNA1 | c.416C>G p.S139C | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- KBTBD3 | c.1004C>A p.S335Y | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.6); PolyPhen probably damaging (1); called by muse, mutect2
- KCNH7 | c.93T>G p.I31M | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KCTD16 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA0319 | c.1249G>T p.E417* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- KRT17 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 34/317 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- LAMA5 | c.5301G>T p.G1767= | Splice Region (SNP) | VAF 37/181 reads (20%) | called by muse, mutect2, varscan2
- MAP7D2 | c.885-1G>T p.X295_splice | Splice Site (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
- NBPF15 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- NPTX2 | c.1022G>A p.W341* | Nonsense Mutation (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
- NRAP | c.4105G>T p.A1369S (on ENST00000359988 / NM_001322945.2; = p.A1334S on NM_006175.4) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUDT9 | c.779A>T p.D260V | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT tolerated (0.17); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- OR1S2 | c.918G>T p.R306S | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHGB7 | c.1777G>C p.A593P | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHF20L1 | c.755T>G p.F252C | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.994); called by muse, mutect2
- PHTF2 | c.2066C>A p.S689* (on ENST00000248550 / NM_001366089.1; = p.S651* on NM_020432.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- PLA2G4E | c.561G>T p.E187D | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.035); called by muse, mutect2
- POLR1F | c.853C>A p.Q285K | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- RYR3 | c.5832G>T p.Q1944H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- SENP6 | c.3106C>T p.Q1036* | Nonsense Mutation (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- SF3B1 | c.550G>T p.V184F | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- SGSM2 | c.2524C>A p.L842M (on ENST00000426855 / NM_001098509.2; = p.L887M on NM_014853.3) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SIPA1L2 | c.2083C>A p.Q695K | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- SLC30A4 | c.274G>C p.V92L | Missense Mutation (SNP) | VAF 99/163 reads (61%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SMARCAL1 | c.2236G>T p.E746* | Nonsense Mutation (SNP) | VAF 45/66 reads (68%) | called by muse, mutect2, varscan2
- SPATA31A3 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 42/746 reads (6%) | called by muse, mutect2
- SPNS2 | c.1078G>T p.A360S | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TANGO6 | c.2746G>T p.D916Y | Missense Mutation (SNP) | VAF 107/169 reads (63%) | SIFT tolerated (0.95); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- TAS2R40 | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.123); called by muse, mutect2
- TMEM132D | c.3255C>A p.C1085* | Nonsense Mutation (SNP) | VAF 74/173 reads (43%) | called by muse, mutect2, varscan2
- TRIM33 | c.2659G>T p.E887* | Nonsense Mutation (SNP) | VAF 72/109 reads (66%) | called by muse, mutect2, varscan2
- TSPYL4 | c.1080C>G p.D360E | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2
- TULP4 | c.1054C>A p.H352N | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- TUT7 | c.4030G>T p.D1344Y | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2
- ALK | c.1104C>T p.H368= | Silent (SNP) | VAF 18/149 reads (12%) | catalogued as rs534481890, COSV66560254; called by muse, mutect2, varscan2
- APPBP2 | c.1692C>T p.P564= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as rs1223254730; called by muse, mutect2, varscan2
- CFAP52 | c.1554C>A p.I518= | Silent (SNP) | VAF 66/103 reads (64%) | called by muse, mutect2, varscan2
- CLDN1 | c.219G>T p.L73= | Silent (SNP) | VAF 68/122 reads (56%) | called by muse, mutect2, varscan2
- COL22A1 | c.4389C>A p.T1463= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as rs747185937; called by muse, mutect2, varscan2
- EXOC4 | c.2586C>A p.I862= | Silent (SNP) | VAF 39/139 reads (28%) | called by muse, mutect2, varscan2
- EZHIP | c.204C>T p.S68= | Silent (SNP) | VAF 19/95 reads (20%) | called by muse, mutect2, varscan2
- FCRL6 | c.462C>T p.H154= | Silent (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- FOXN3 | c.561G>C p.S187= | Silent (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- GPNMB | c.444C>T p.T148= | Silent (SNP) | VAF 125/295 reads (42%) | catalogued as rs371662186; called by muse, mutect2, varscan2
- HHIPL2 | c.1197G>T p.S399= | Silent (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2
- JAKMIP3 | c.489C>T p.G163= | Silent (SNP) | VAF 120/194 reads (62%) | catalogued as rs369892382; called by muse, mutect2, varscan2
- LDHC | c.325C>T p.L109= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as rs1329425987; called by muse, mutect2
- OR2A14 | c.42G>A p.P14= | Silent (SNP) | VAF 52/174 reads (30%) | catalogued as rs1405663096, COSV68718116; called by muse, mutect2, varscan2
- PKD1L1 | c.2643G>T p.V881= | Silent (SNP) | VAF 11/137 reads (8%) | called by muse, mutect2
- RUVBL1 | c.72G>T p.L24= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV59474835; called by muse, mutect2, varscan2
- SGSM2 | c.2526G>T p.L842= (on ENST00000426855 / NM_001098509.2; = p.L887= on NM_014853.3) | Silent (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- VNN1 | c.726G>A p.L242= | Silent (SNP) | VAF 26/293 reads (9%) | called by muse, mutect2
- WNK2 | c.3471T>C p.F1157= | Silent (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- ZNF277 | c.1200C>A p.T400= | Silent (SNP) | VAF 34/88 reads (39%) | called by muse, mutect2, varscan2
- HOATZ | chr11:111513511 A>T | 5'Flank (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85404G>T | Intron (SNP) | VAF 18/130 reads (14%) | called by muse, mutect2, varscan2
- PHGDH | c.-2C>A | 5'UTR (SNP) | VAF 166/248 reads (67%) | called by muse, mutect2, varscan2
